TCGA case TCGA-25-2409 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dce71741-ccbe-40b7-a0b8-2048d07187a4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Dead; Days to death: 821 days (2.2 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 71.9 years (26,267 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 182 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 72.7 years (26,571 days); Days to diagnosis: 304 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 304 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 304 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 821 days (2.2 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-25-2409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 1.5; Shortest dimension: 0.4.
  Slide TCGA-25-2409-01A-01-BS1: Section location: Bottom; Percent tumor cells: 94; Percent tumor nuclei: 95; Percent normal cells: 1; Percent necrosis: 1; Percent stromal cells: 4.
  Slide TCGA-25-2409-01A-01-TS1: Section location: Top; Percent tumor cells: 94; Percent tumor nuclei: 95; Percent normal cells: 1; Percent necrosis: 1; Percent stromal cells: 4.
- Sample TCGA-25-2409-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-25-2409-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxotere.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 821 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 821 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 304 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-25-2409-01): tumor purity 0.72, ploidy 3.79, whole-genome doublings 1 (call status: legacy_call).
